Somatic mutation profile of tumor specimen C3L-01687-01 (aliquot CPT0094630010) from CPTAC case C3L-01687, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: female; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage IIB; Tumor grade: G2; Age at diagnosis: 79.0 years (28,838 days).
Specimen C3L-01687-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 183d91ed-4910-479d-8654-99d681eb428e.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-01687-31 (Blood Derived Normal), aliquot CPT0094670002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/3c3c8e6f-6adf-47d1-833d-a9282a996a8f

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 6 silent, 9 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 22, Silent 6, Intron 6, Splice Region 2, Frame Shift Ins 2, Nonsense Mutation 1, 5'Flank 1, In Frame Del 1, 3'UTR 1, Frame Shift Del 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN2A | c.247C>G p.H83D | Missense Mutation (SNP) | VAF 90/450 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs121913385, CM053801, CM056557, COSV58682852, COSV58685578, COSV58690009; ClinVar: likely pathogenic; called by muse, mutect2, varscan2
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 69/411 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADD2 | c.705G>A p.A235= | Splice Region (SNP) | VAF 6/46 reads (13%) | catalogued as rs781804198, COSV52472118; called by muse, mutect2, varscan2
- ANKRD50 | c.997T>G p.L333V | Missense Mutation (SNP) | VAF 71/377 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV72385550; called by muse, mutect2, varscan2
- CDH10 | c.231G>C p.K77N | Missense Mutation (SNP) | VAF 26/178 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.541); catalogued as COSV52580410, COSV52598251; called by muse, mutect2
- DPYS | c.1072G>A p.V358I | Missense Mutation (SNP) | VAF 73/544 reads (13%) | SIFT tolerated (0.35); PolyPhen benign (0.014); catalogued as rs769403392; called by muse, mutect2, varscan2
- FCRL1 | c.104C>A p.T35N | Missense Mutation (SNP) | VAF 50/327 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs1407942494; called by muse, mutect2, varscan2
- FLNA | c.1168G>A p.G390S | Missense Mutation (SNP) | VAF 29/519 reads (6%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.983); catalogued as rs199766573; called by muse, mutect2
- HERC2 | c.1229C>T p.P410L | Missense Mutation (SNP) | VAF 36/235 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); catalogued as rs779830734, COSV55334806; called by muse, mutect2, varscan2
- KAT6B | c.5356G>A p.E1786K | Missense Mutation (SNP) | VAF 26/420 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.957); catalogued as rs906740657, COSV54744157; called by muse, mutect2
- LAMA1 | c.730C>T p.R244W | Missense Mutation (SNP) | VAF 57/538 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.97); catalogued as rs200626690; called by muse, mutect2, varscan2
- PKN2 | c.2533G>A p.V845M | Missense Mutation (SNP) | VAF 16/116 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.059); catalogued as COSV65143304; called by mutect2, varscan2
- PRKD2 | c.1325C>T p.P442L | Missense Mutation (SNP) | VAF 26/162 reads (16%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as rs763539356, COSV99354200; called by muse, mutect2
- RALB | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 80/464 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.936); catalogued as rs1388854390; called by muse, mutect2, varscan2
- RNMT | c.716G>A p.R239Q | Missense Mutation (SNP) | VAF 32/361 reads (9%) | SIFT deleterious (0.04); PolyPhen probably damaging (1); catalogued as rs1438601973, COSV100054832; called by muse, mutect2
- SLC35F3 | c.1091T>C p.I364T (on ENST00000366617 / NM_001300845.1; = p.I433T on NM_173508.4) | Missense Mutation (SNP) | VAF 34/532 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100784849; called by muse, mutect2
- SLC4A3 | c.223C>T p.R75W | Missense Mutation (SNP) | VAF 7/51 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764732530; called by muse, mutect2, varscan2
- THBS4 | c.783C>T p.C261= | Splice Region (SNP) | VAF 29/219 reads (13%) | catalogued as rs561944130; called by muse, mutect2, varscan2
- TRPM1 | c.2372C>T p.T791M | Missense Mutation (SNP) | VAF 49/434 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.001); catalogued as rs377044822; called by muse, mutect2, varscan2
- UROC1 | c.1687G>A p.D563N | Missense Mutation (SNP) | VAF 98/523 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs372570937; called by muse, mutect2, varscan2
- AHCTF1 | c.4465G>A p.A1489T (on ENST00000366508; = p.A1463T on NM_015446.5) | Missense Mutation (SNP) | VAF 17/202 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.015); called by muse, mutect2
- ANKFN1 | c.3187G>A p.D1063N (on ENST00000653862; = p.D916N on NM_001365758.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 48/446 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.746); called by muse, mutect2, varscan2
- BRINP3 | c.808G>T p.E270* | Nonsense Mutation (SNP) | VAF 38/263 reads (14%) | called by muse, mutect2, varscan2
- DIDO1 | c.2609_2613del p.K870Tfs*8 | Frame Shift Del (DEL) | VAF 28/179 reads (16%) | called by mutect2, pindel, varscan2
- DIS3 | c.1518dup p.A507Cfs*2 | Frame Shift Ins (INS) | VAF 35/283 reads (12%) | called by mutect2, pindel, varscan2
- NBEA | c.3908T>A p.V1303D | Missense Mutation (SNP) | VAF 44/379 reads (12%) | SIFT tolerated, low confidence (0.16); PolyPhen possibly damaging (0.601); called by muse, mutect2, varscan2
- PKD1L3 | c.1522dup p.I508Nfs*2 | Frame Shift Ins (INS) | VAF 16/126 reads (13%) | called by mutect2, pindel, varscan2
- TP53 | c.705_719del p.Y236_S240del | In Frame Del (DEL) | VAF 50/341 reads (15%) | called by mutect2, pindel
- VDR | c.1316G>A p.G439D | Missense Mutation (SNP) | VAF 17/212 reads (8%) | called by muse, mutect2
- SAGE1 | c.1365C>T p.N455= | Silent (SNP) | VAF 26/149 reads (17%) | catalogued as rs782556186, COSV100186857; called by muse, mutect2, varscan2
- SDHC | c.276C>T p.L92= | Silent (SNP) | VAF 68/427 reads (16%) | catalogued as COSV100713603; called by muse, mutect2, varscan2
- SEC16A | c.1257G>A p.G419= | Silent (SNP) | VAF 43/294 reads (15%) | called by muse, mutect2, varscan2
- SHANK1 | c.4740A>G p.P1580= | Silent (SNP) | VAF 58/258 reads (22%) | catalogued as rs763099836; called by muse, mutect2, varscan2
- STK39 | c.1116T>C p.G372= | Silent (SNP) | VAF 15/274 reads (5%) | called by muse, mutect2
- ZNF217 | c.1659A>G p.Q553= | Silent (SNP) | VAF 72/504 reads (14%) | catalogued as rs752565233; called by muse, mutect2
- CCDC74B | c.296-157C>T | Intron (SNP) | VAF 14/268 reads (5%) | catalogued as rs781529448; called by muse, mutect2
- DENND3 | c.956+2228G>A | Intron (SNP) | VAF 31/178 reads (17%) | called by muse, mutect2, varscan2
- OBSCN | c.5138-1767C>A | Intron (SNP) | VAF 37/360 reads (10%) | called by muse, mutect2, varscan2
- RNA5-8SP2 | chr16:34159592 C>T | 5'Flank (SNP) | VAF 11/86 reads (13%) | catalogued as rs752328712; called by muse, mutect2, varscan2
- SEH1L | c.*32T>C | 3'UTR (SNP) | VAF 83/250 reads (33%) | called by muse, mutect2, varscan2
- TAFA5 | c.112+54989C>T | Intron (SNP) | VAF 30/148 reads (20%) | catalogued as rs867817171; called by muse, mutect2
- TGIF1 | c.-44-29A>G | Intron (SNP) | VAF 111/419 reads (26%) | called by muse, mutect2, varscan2
- TTN | c.34265-3066_34265-3038del | Intron (DEL) | VAF 25/251 reads (10%) | called by mutect2, pindel
- UBL4A | c.-9G>A | 5'UTR (SNP) | VAF 12/83 reads (14%) | called by muse, mutect2, varscan2
